Somatic mutation profile of tumor specimen BA2587D (aliquot aq-BA2587D) from BEATAML1.0 case 2215, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, CBF-beta/MYH11; Tissue or organ of origin: Bone marrow; Age at diagnosis: 64.9 years (23,720 days).
Specimen BA2587D: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 09aaf46c-59fd-47aa-a7a5-6a50457431fb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2107D (Solid Tissue Normal), aliquot aq-BA2107D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/edb195d3-68fb-4aff-92f5-9717219fe949

The open-access MAF lists 10 somatic variants for this specimen: 5 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Silent 4, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NPAP1 | c.1868C>A p.P623Q | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0.087); catalogued as COSV61508744; called by muse, mutect2
- SLC19A1 | c.247G>A p.V83M | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.36); catalogued as rs1332426561; called by muse, mutect2
- ABCA7 | c.508G>A p.G170R | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT tolerated (0.32); PolyPhen benign (0); called by muse, mutect2, varscan2
- CSE1L | c.1957C>A p.Q653K | Missense Mutation (SNP) | VAF 5/73 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.542); called by muse, mutect2
- PEAK1 | c.5008C>T p.P1670S | Missense Mutation (SNP) | VAF 3/49 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- ADGRG6 | c.390C>A p.S130= | Silent (SNP) | VAF 5/63 reads (8%) | called by muse, mutect2
- BCL11A | c.2004G>T p.P668= (on ENST00000335712 / NM_001365609.1; = p.P702= on NM_018014.4) | Silent (SNP) | VAF 4/26 reads (15%) | catalogued as rs1461539448, COSV59624664; called by muse, mutect2
- RBM5 | c.1810C>A p.R604= | Silent (SNP) | VAF 4/38 reads (11%) | catalogued as COSV61737968; called by muse, mutect2
- SYT12 | c.438C>T p.T146= | Silent (SNP) | VAF 14/23 reads (61%) | catalogued as rs1181914080; called by muse, mutect2, varscan2
- TMEM75 | n.1025G>T | RNA (SNP) | VAF 6/68 reads (9%) | called by muse, mutect2
